Gene-level copy-number profile of tumor specimen TCGA-92-8064-01A from TCGA case TCGA-92-8064, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 58.6 years (21,417 days).
Specimen TCGA-92-8064-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.00f40773-ae72-40a7-8990-65d706b1a2a6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-92-8064-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4f263ee4-966a-4092-90aa-24d046fbdfba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 311; copy number 2: 22,731; copy number 3: 20,448; copy number 4: 9,392; copy number 5: 4,319; copy number 6: 174; copy number 7: 1,019; copy number 8: 107; copy number 9: 35; copy number 10: 81; copy number 11: 472; copy number 12: 587; copy number 13: 77; copy number 16: 1; copy number 18: 7; copy number 29: 53.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-92-8064-01A-11D-2243-01): tumor purity 0.31, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,537 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:57,048,350–62,464,070, 82 genes, copy number 8–12 (broad region; genes not listed).
- chr2:119,993,199–126,702,942, 67 genes, copy number 11–18 (broad region; genes not listed).
- chr2:148,595,158–149,026,759, 9 genes, copy number 5: RPS29P8, EPC2, RNU2-9P, UBBP3, KIF5C-AS1, RPS20P13, USP8P2, KIF5C, AC105402.1.
- chr2:149,068,596–149,068,910, 1 gene, copy number 5: TXNP5.
- chr3:104,063,039–198,222,513, 1,660 genes, copy number 5–11 (broad region; genes not listed).
- chr4:53,986,587–57,724,655, 88 genes, copy number 7 (broad region; genes not listed).
- chr5:43,192,071–43,280,850, 1 gene, copy number 9 (within-gene range 4–9): NIM1K.
- chr5:43,231,812–45,895,970, 34 genes, copy number 9: TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:47,878,028–48,952,781, 7 genes, copy number 7–16: PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1.
- chr6:50,514,035–50,773,033, 3 genes, copy number 11 (within-gene range 3–11): AL360175.1, AL135908.1, TFAP2D.
- chr6:53,929,982–54,266,280, 1 gene, copy number 5 (within-gene range 3–5): MLIP.
- chr6:54,190,206–68,242,364, 105 genes, copy number 5–8 (broad region; genes not listed).
- chr7:55,019,017–56,080,670, 38 genes, copy number 6 (within-gene range 4–6): EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2.
- chr8:96,493,813–145,066,685, 768 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:14,475–43,045,120, 776 genes, copy number 5–12 (broad region; genes not listed).
- chr10:15,513,954–18,545,651, 39 genes, copy number 6 (within-gene range 1–6): ITGA8, MINDY3, AL358033.1, FTLP19, RNU6-1075P, LINC02654, PTER, RNU2-18P, C1QL3, AL353576.1, RSU1, AC073367.1, AL365215.1, AL365215.2, CUBN, AC067747.1, TRDMT1, VIM-AS1, VIM, AL133415.1, ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1, CACNB2, AL390783.1, AL450384.2, AL450384.1.
- chr11:48,880,111–54,725,816, 68 genes, copy number 6 (broad region; genes not listed).
- chr11:68,980,021–70,436,584, 47 genes, copy number 29: MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 29: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr11:73,872,667–77,215,241, 114 genes, copy number 7–13 (within-gene range 4–13) (broad region; genes not listed).
- chr11:102,110,447–107,963,482, 98 genes, copy number 8–10 (within-gene range 2–10) (broad region; genes not listed).
- chr12:19,404,045–19,720,801, 1 gene, copy number 5 (within-gene range 3–5): AEBP2.
- chr12:19,508,904–47,079,959, 400 genes, copy number 5–6 (broad region; genes not listed).
- chr14:18,333,726–38,041,442, 672 genes, copy number 5–12 (within-gene range 3–12) (broad region; genes not listed).
- chr16:28,341,434–29,370,272, 1 gene, copy number 5 (within-gene range 2–5): AC009093.11.
- chr16:28,749,959–35,912,516, 459 genes, copy number 5 (broad region; genes not listed).
- chr19:37,907,208–39,738,029, 103 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:87,250–42,063,969, 889 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 311. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
